Somatic mutation profile of tumor specimen TCGA-D3-A2JO-06A (aliquot TCGA-D3-A2JO-06A-11D-A196-08) from TCGA case TCGA-D3-A2JO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.0 years (18,627 days).
Specimen TCGA-D3-A2JO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a05a1620-d030-45e4-b6e1-161f5f133522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JO-10A (Blood Derived Normal), aliquot TCGA-D3-A2JO-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34173570-62f7-4171-b38e-5525b07d5976

The open-access MAF lists 720 somatic variants for this specimen: 461 protein-altering or splice-affecting, 236 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 422, Silent 236, Nonsense Mutation 25, Intron 10, Splice Site 6, RNA 5, Splice Region 4, Frame Shift Del 4, 5'Flank 3, 3'UTR 3, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.447+1G>A p.X149_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as rs1559053022, COSV58593650; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779517, CM000348, COSV58590095; ClinVar: pathogenic; called by muse, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 62/179 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TRIO | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs879255626, COSV60078769; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA12 | c.2747C>A p.S916Y (on ENST00000272895 / NM_173076.3; = p.S598Y on NM_015657.3) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV55968910, COSV55978314; called by mutect2, varscan2
- ABCA4 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV64675879; called by muse, varscan2
- ABCB10 | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60622683; called by muse, mutect2, varscan2
- ABCC6 | c.2588G>A p.G863E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV52746384; called by muse, mutect2, varscan2
- AC004997.1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.42); catalogued as rs757314887, COSV53165172; called by mutect2, varscan2
- ACE | c.2163A>G p.I721M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1424703433, COSV52010776; called by muse, mutect2, varscan2
- ACMSD | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs757421443, COSV51607251; called by muse, mutect2, varscan2
- ACVR1C | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as rs775081249, COSV54643616; called by mutect2, varscan2
- ADAM29 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV63666072; called by muse, mutect2, varscan2
- ADAM29 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.331); catalogued as COSV63666081; called by mutect2, varscan2
- ADAMTS18 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV51420088; called by muse, varscan2
- ADAMTS19 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50753275; called by muse, mutect2, varscan2
- ADAMTSL1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as COSV52820694; called by muse, mutect2, varscan2
- ADGRG1 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV65636240; called by muse, mutect2, varscan2
- ADTRP | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57644773; called by muse, mutect2, varscan2
- AKAP3 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV57418847; called by mutect2, varscan2
- AKAP9 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV62353234; called by muse, mutect2
- ALDH1B1 | c.1453T>C p.F485L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV66620310; called by muse, mutect2, varscan2
- ALDH5A1 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV62374212; called by muse, varscan2
- ALPK2 | c.4733G>C p.R1578P | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as COSV64493464, COSV64495035; called by muse, mutect2, varscan2
- AMPD3 | c.1184C>T p.P395L (on ENST00000396553 / NM_001025389.2; = p.P404L on NM_000480.3) | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761471998, COSV67331843; called by muse, varscan2
- ANKRD11 | c.2450A>C p.Y817S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV56367067; called by muse, mutect2, varscan2
- ANKRD30A | c.1694C>T p.S565F (on ENST00000611781; = p.S509F on NM_052997.2) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV64616386; called by muse, mutect2, varscan2
- ANKS1B | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61364633; called by muse, mutect2, varscan2
- ANO3 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56800926; called by muse, mutect2, varscan2
- AQR | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV50043248; called by muse, mutect2, varscan2
- ARID2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV57596634; called by mutect2, varscan2
- ARID2 | c.2890G>T p.G964* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as COSV57599469; called by mutect2, varscan2
- ARMC2 | c.2312G>C p.G771A | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV64552426; called by muse, mutect2, varscan2
- ARMC4 | c.2956G>A p.A986T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972164483, COSV59469425; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV63438590; called by muse, mutect2, varscan2
- ARSF | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV63840443; called by muse, mutect2, varscan2
- ASPM | c.5270C>T p.S1757L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV54134611; called by mutect2, varscan2
- ASRGL1 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57125723; called by muse, mutect2, varscan2
- ASTN2 | c.935A>T p.D312V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV57800942; called by mutect2, varscan2
- ASXL2 | c.895T>C p.C299R | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55463888; called by muse, mutect2, varscan2
- ASXL3 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52473696, COSV99324754; called by muse, mutect2
- ATF6B | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV64352309; called by muse, mutect2, varscan2
- ATG2B | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV63424596; called by muse, mutect2, varscan2
- ATP10D | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV99905652; called by muse, mutect2, varscan2
- ATP13A5 | c.449A>T p.K150I | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV60872557; called by muse, mutect2, varscan2
- AWAT2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52144064, COSV99339699; called by muse, mutect2, varscan2
- B4GALT4 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs145839681; called by muse, mutect2, varscan2
- BAG6 | c.2392C>T p.L798F (on ENST00000676571; = p.L751F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs747960997, COSV52993308; called by muse, mutect2, varscan2
- BAIAP3 | c.2503G>A p.G835R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as rs753248180, COSV50104623; called by muse, mutect2, varscan2
- BASP1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100493487, COSV59472247; called by muse, mutect2, varscan2
- BASP1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1478735559, COSV100493739; called by mutect2, varscan2
- BRDT | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866429729, COSV100746398; called by muse, mutect2, varscan2
- BTBD9 | c.1641G>A p.E547= | Splice Region (SNP) | VAF 30/65 reads (46%) | catalogued as COSV58432065; called by muse, mutect2, varscan2
- BTD | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as COSV57729965; called by muse, mutect2, varscan2
- C10orf71 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV60510538; called by muse, mutect2, varscan2
- C19orf57 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.763); catalogued as COSV100694709; called by mutect2, varscan2
- C8B | c.860A>G p.H287R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.791); catalogued as COSV64778716; called by muse, mutect2, varscan2
- CA2 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs377003627; called by mutect2, varscan2
- CADPS2 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs755235522, COSV57375941; called by muse, mutect2, varscan2
- CALCOCO2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV51952954; called by muse, mutect2, varscan2
- CAMKK1 | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as COSV99340314; called by mutect2, varscan2
- CAP2 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV57733685; called by mutect2, varscan2
- CCBE1 | c.213-1G>A p.X71_splice | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as rs201030273, COSV67950757; called by muse, mutect2, varscan2
- CCDC110 | c.1455A>C p.E485D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56872539; called by muse, varscan2
- CCDC7 | c.3131G>A p.G1044E | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56548393; called by muse, mutect2, varscan2
- CCDC74B | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1388761371, COSV60103119; called by mutect2, varscan2
- CD14 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57371136; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CD5 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV61718132; called by muse, mutect2, varscan2
- CDH10 | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV52590328; called by muse, mutect2, varscan2
- CDH16 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55338436; called by muse, mutect2, varscan2
- CDH26 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs778225410, COSV54850311; called by mutect2, varscan2
- CDX4 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65171637; called by mutect2, varscan2
- CEPT1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62959687; called by muse, mutect2, varscan2
- CFAP47 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs1483129646, COSV52888900; called by muse, mutect2, varscan2
- CFAP77 | c.416G>C p.W139S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58010376, COSV58014229; called by muse, mutect2, varscan2
- CFHR1 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV57628268; called by muse, mutect2
- CGNL1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs781183314, COSV55572111; called by muse, mutect2, varscan2
- CHD7 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV71113063; called by muse, mutect2, varscan2
- CHRD | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.554); catalogued as COSV52607380; called by muse, mutect2, varscan2
- CLTCL1 | c.3460G>C p.V1154L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV54235548; called by muse, mutect2, varscan2
- CMPK2 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56775642; called by muse, mutect2, varscan2
- CMYA5 | c.7829G>T p.R2610I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV71408056; called by mutect2, varscan2
- CNST | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63622196; called by muse, mutect2, varscan2
- CNTNAP2 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs866697251, COSV62225965, COSV62243617; called by muse, mutect2, varscan2
- CNTNAP2 | c.1551C>A p.F517L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV62225972; called by mutect2, varscan2
- CNTNAP4 | c.2255T>C p.L752S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV56692478; called by muse, mutect2, varscan2
- COA5 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.75); catalogued as COSV60831365; called by muse, mutect2, varscan2
- COIL | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53595923; called by muse, varscan2
- COL11A1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.017); catalogued as COSV100616048, COSV62190243; called by muse, mutect2, varscan2
- COL4A4 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306447, COSV61634618; called by muse, mutect2, varscan2
- COL5A1 | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65672680; called by muse, mutect2, varscan2
- COL6A6 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs1474900658, COSV62032166; called by muse, mutect2, varscan2
- COLEC12 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as COSV68372430; called by muse, mutect2, varscan2
- COPS2 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV54644468, COSV54644790; called by muse, varscan2
- CPA2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV55979697; called by muse, mutect2, varscan2
- CPA6 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52737280; called by muse, mutect2, varscan2
- CPT1A | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as COSV55759015; called by muse, mutect2, varscan2
- CRIM1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs771535773, COSV54860184; called by mutect2, varscan2
- CSMD3 | c.10382G>A p.G3461E (on ENST00000297405 / NM_001363185.1; = p.G3292E on NM_052900.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866609923, COSV52257989; called by muse, mutect2, varscan2
- CST1 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59055880; called by muse, mutect2, varscan2
- CST1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.855); catalogued as COSV59055892; called by mutect2, varscan2
- CUL4B | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV68138616; called by muse, mutect2, varscan2
- CYLC2 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV66337427; called by mutect2, varscan2
- CYLC2 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV66336769; called by muse, mutect2, varscan2
- CYP24A1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV53775850; called by muse, mutect2, varscan2
- CYP2B6 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57844997; called by muse, mutect2, varscan2
- CYP4F11 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs147948717, COSV56128546; called by muse, mutect2, varscan2
- CYTH4 | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV50634387; called by muse, mutect2, varscan2
- DBH | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs547488212, COSV55041872; called by muse, mutect2, varscan2
- DDX42 | c.1144T>A p.C382S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV63790813; called by muse, varscan2
- DDX60L | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV52718163; called by mutect2, varscan2
- DEFB128 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1568472990, COSV57685794; called by mutect2, varscan2
- DGAT1 | c.1168T>C p.Y390H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782087919, COSV60048866; called by muse, mutect2, varscan2
- DGKA | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as COSV59387590; called by muse, varscan2
- DGKB | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51805079, COSV51823120; called by muse, mutect2, varscan2
- DIAPH3 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV57375968; called by mutect2, varscan2
- DISP3 | c.2188T>C p.W730R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.412); catalogued as COSV53833534; called by muse, varscan2
- DNAH3 | c.6340G>A p.D2114N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.982); catalogued as COSV54538206; called by muse, mutect2, varscan2
- DNAH3 | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs768867312, COSV54538227; called by mutect2, varscan2
- DNAH5 | c.10327G>A p.D3443N | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV54213154; called by muse, mutect2, varscan2
- DNAH5 | c.6149C>T p.S2050F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs865859969, COSV54207857; called by muse, mutect2, varscan2
- DNAH6 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1373965792, COSV52857094, COSV52873130; called by muse, mutect2, varscan2
- DNAH8 | c.9527T>A p.L3176H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59467062; called by mutect2, varscan2
- DNER | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59163486; called by muse, varscan2
- DNMT1 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.038); catalogued as COSV61581834; called by mutect2, varscan2
- DOCK1 | c.4979C>T p.S1660F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54746164, COSV54750880; called by muse, mutect2, varscan2
- DOCK3 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522532; called by muse, mutect2, varscan2
- DOCK4 | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV69855135; called by muse, mutect2
- DPYSL4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as COSV58308937; called by muse, varscan2
- DSC3 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs267605145, COSV64571842; called by muse, mutect2, varscan2
- DST | c.4967C>T p.S1656F | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV55027443; called by muse, mutect2, varscan2
- DYRK4 | c.1497G>T p.M499I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV50542468; called by muse, mutect2, varscan2
- EFHB | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV55551172; called by muse, mutect2, varscan2
- ERN1 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV70503649; called by mutect2, varscan2
- EVC | c.201G>C p.K67N | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV53836013, COSV99382719; called by muse, mutect2, varscan2
- EVX1 | c.684+1G>A p.X228_splice | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as COSV56085815; called by muse, mutect2, varscan2
- F8 | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557278285, CM062670, COSV64276626; called by muse, mutect2
- FAM47B | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV61455522; called by muse, mutect2, varscan2
- FAM47C | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV63725535; called by muse, mutect2, varscan2
- FAM90A1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV56711820; called by muse, mutect2
- FARP1 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.416); catalogued as COSV60343237; called by mutect2, varscan2
- FBN2 | c.4492C>T p.Q1498* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV52531609; called by muse, mutect2, varscan2
- FBXO10 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs752526134, COSV52834536; called by muse, mutect2, varscan2
- FCAMR | c.450G>A p.W150* | Nonsense Mutation (SNP) | VAF 42/66 reads (64%) | catalogued as rs267598335, COSV61368810; called by muse, mutect2, varscan2
- FGF23 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV52977254; called by muse, mutect2, varscan2
- FLT4 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV56116831; called by muse, mutect2, varscan2
- FLT4 | c.60C>G p.G20= | Splice Region (SNP) | VAF 3/25 reads (12%) | catalogued as COSV56106323, COSV56116854, COSV56120067; called by muse, mutect2
- FRAS1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs200764508, COSV53628624; ClinVar: uncertain significance; called by mutect2, varscan2
- FZD8 | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65968171, COSV65968197; called by mutect2, varscan2
- GABRG2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV62715623; called by mutect2, varscan2
- GAS2 | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53406359, COSV53410343; called by muse, mutect2, varscan2
- GATD1 | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV60593044; called by muse, varscan2
- GBA3 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72438265; called by muse, mutect2
- GCNT1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1311550625, COSV65058317; called by muse, mutect2, varscan2
- GGA2 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV100564706; called by mutect2, varscan2
- GIGYF2 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1228793071, COSV65250825; called by mutect2, varscan2
- GLYATL2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs1375976346, COSV54850843; called by mutect2, varscan2
- GNAS | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV58341829; called by mutect2, varscan2
- GNL3L | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100328408; called by mutect2, varscan2
- GOT1L1 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100294521; called by mutect2, varscan2
- GPHN | c.893A>G p.N298S (on ENST00000315266 / NM_001377519.1; = p.N331S on NM_020806.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.678); catalogued as COSV59487510; called by muse, mutect2, varscan2
- GPKOW | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1557091438, COSV50244096; called by muse, mutect2, varscan2
- GPRASP1 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV64356153; called by muse, mutect2, varscan2
- GRIA3 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.171); catalogued as COSV52056297, COSV52081133; called by mutect2, varscan2
- GRK7 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.784); catalogued as rs199515525, COSV53823755; called by mutect2, varscan2
- GRM3 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV64471509, COSV64472119; called by mutect2, varscan2
- GSDMC | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.168); catalogued as COSV52697500; called by mutect2, varscan2
- HCN3 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs370091278; called by muse, mutect2, varscan2
- HECW2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53668403; called by muse, varscan2
- HEPH | c.3091G>A p.V1031I (on ENST00000343002; = p.V764I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV57965726, COSV57968550; called by muse, mutect2, varscan2
- HEPHL1 | c.3322G>A p.G1108S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV59894435; called by muse, mutect2, varscan2
- HEXIM2 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1470507890, COSV56236969; called by mutect2, varscan2
- HGF | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776090604, COSV55945716; called by mutect2, varscan2
- HLA-DRA | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as rs867285682, COSV66622958; called by mutect2, varscan2
- HNRNPK | c.43A>C p.T15P | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV57937173; called by muse, mutect2, varscan2
- HUWE1 | c.6641G>A p.R2214Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53341812; called by mutect2, varscan2
- IGHD | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1313725576, COSV101162896; called by muse, mutect2, varscan2
- IGLV5-52 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs775017748; called by muse, mutect2, varscan2
- IKZF1 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV58782694, COSV58783388; called by muse, mutect2
- IL1R1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as COSV52105979; called by muse, mutect2, varscan2
- IL36A | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV52083557; called by muse, mutect2, varscan2
- IMPG2 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs745427362, COSV51982721; called by muse, mutect2, varscan2
- INTS11 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60089611; called by muse, mutect2
- IPO9 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64232835; called by mutect2, varscan2
- IQCE | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1008496674, COSV58076387; called by muse, mutect2, varscan2
- ITM2C | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV58399896; called by muse, mutect2, varscan2
- KCNA4 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.229); catalogued as COSV60251477, COSV60254330; called by muse, mutect2, varscan2
- KCNA4 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.354); catalogued as COSV60254339; called by mutect2, varscan2
- KCNH3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs375542018; called by mutect2, varscan2
- KCNN1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.123); catalogued as COSV55840657; called by muse, mutect2, varscan2
- KCNT1 | c.3490G>A p.E1164K (on ENST00000488444; = p.E1169K on NM_020822.3) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.53); catalogued as rs768746178, COSV53706738; called by mutect2, varscan2
- KCTD18 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751451505, COSV63344888; called by muse, mutect2, varscan2
- KCTD19 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV100430973; called by mutect2, varscan2
- KCTD19 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100430975; called by muse, mutect2, varscan2
- KDM4C | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV67189660; called by mutect2, varscan2
- KIF23 | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52981626; called by muse, mutect2, varscan2
- KLHL1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs540276903, COSV64777509; called by mutect2, varscan2
- KLHL2 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV56980516; called by muse, mutect2
- KRT8 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV53178441; called by mutect2, varscan2
- LAMB2 | c.1225+2T>G p.X409_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59736040; called by muse, mutect2, varscan2
- LILRB2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.685); catalogued as COSV58747205; called by muse, mutect2, varscan2
- LOXL2 | c.1903T>C p.F635L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101207702, COSV66692644; called by muse, mutect2, varscan2
- LPAR1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.577); catalogued as rs748796192, COSV62688148; called by muse, mutect2, varscan2
- LRIG3 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.541); catalogued as COSV57867338; called by muse, mutect2, varscan2
- LRP1B | c.4619G>T p.C1540F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67252614; called by muse, mutect2, varscan2
- LRP2 | c.5120C>T p.S1707F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs745788682, COSV55565025; called by muse, mutect2, varscan2
- LRRC7 | c.727C>T p.Q243* (on ENST00000651989 / NM_001370785.2; = p.Q210* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/192 reads (16%) | catalogued as COSV50533421, COSV50652759, COSV99226771; called by mutect2, varscan2
- LTB4R | c.631C>G p.R211G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.306); catalogued as COSV51867030; called by muse, mutect2, varscan2
- LTF | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51606643; called by muse, mutect2, varscan2
- MAGEC1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 52/231 reads (23%) | catalogued as COSV53577785; called by muse, mutect2, varscan2
- MAGEC2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56000644; called by muse, mutect2, varscan2
- MAML2 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV73264275; called by muse, mutect2, varscan2
- MAP1A | c.8308C>G p.Q2770E | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.636); catalogued as rs1158614651, COSV55811199; called by muse, mutect2, varscan2
- MARCHF2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as rs747473271, COSV53105356; called by muse, mutect2, varscan2
- MCTP2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs764405023, COSV59147303; called by muse, mutect2, varscan2
- MED13 | c.6086C>T p.S2029F | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67265584; called by muse, mutect2, varscan2
- MEGF6 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.023); catalogued as rs768019835, COSV62993911; called by mutect2, varscan2
- MEPE | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV100734954; called by mutect2, varscan2
- MGAT2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.262); catalogued as COSV100023552; called by muse, mutect2, varscan2
- MGAT2 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100023553; called by muse, mutect2, varscan2
- MGAT4C | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV59835583; called by muse, mutect2, varscan2
- MPHOSPH10 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV54906552; called by muse, varscan2
- MROH5 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs1399033910, COSV71302330; called by muse, varscan2
- MTUS2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV70918977; called by muse, mutect2, varscan2
- MUC16 | c.30563C>T p.S10188F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV67480969; called by muse, mutect2, varscan2
- MUC16 | c.27108G>A p.M9036I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV67480973; called by mutect2, varscan2
- MUC16 | c.19516G>A p.E6506K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV67480988; called by muse, mutect2, varscan2
- MUC16 | c.8463G>A p.M2821I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs267605807, COSV67472890; called by mutect2, varscan2
- MUC20 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.134); catalogued as COSV57852840; called by mutect2, varscan2
- MYH1 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV56853504; called by muse, mutect2, varscan2
- MYH2 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as COSV55443995; called by mutect2, varscan2
- MYH7 | c.3768G>A p.M1256I | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV62521785; called by mutect2, varscan2
- MYH9 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV53390582; called by muse, varscan2
- MYLK | c.5570T>C p.I1857T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274171468, COSV60616706; called by muse, mutect2, varscan2
- MYLK2 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.197); catalogued as rs750838459, COSV65659609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYNN | c.1050A>T p.R350S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62991819; called by mutect2, varscan2
- MYO15A | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.084); catalogued as COSV52761620; called by muse, mutect2, varscan2
- MYOCD | c.2298G>C p.K766N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV58508208, COSV58512948; called by muse, mutect2, varscan2
- MYOM3 | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.371); catalogued as rs781771524, COSV58397617; called by mutect2, varscan2
- NAALAD2 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758876574, COSV58963917; called by muse, mutect2, varscan2
- NANOS3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV59249476; called by muse, mutect2, varscan2
- NCOR2 | c.6861C>G p.I2287M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.623); catalogued as COSV62301316; called by muse, varscan2
- NDST4 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52110407; called by muse, mutect2, varscan2
- NEB | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51104723, COSV51440494; called by muse, mutect2, varscan2
- NEBL | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV65799968; called by muse, mutect2, varscan2
- NECTIN2 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 119/370 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.309); catalogued as COSV52978901; called by muse, mutect2, varscan2
- NFXL1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61199996, COSV61200203; called by mutect2, varscan2
- NIPAL4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61730532, COSV61730742; called by mutect2, varscan2
- NISCH | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs779642718, COSV61900065; called by muse, mutect2, varscan2
- NLRP8 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.326); catalogued as COSV52591261; called by muse, mutect2, varscan2
- NMS | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV65259058; called by muse, mutect2, varscan2
- NOP53 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55882579; called by muse, mutect2, varscan2
- NOX5 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756965311, COSV52986037, COSV99533727; called by mutect2, varscan2
- NPBWR2 | c.449T>A p.V150E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100871120; called by muse, mutect2, varscan2
- NPHP3 | c.2935C>T p.P979S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58632058; called by muse, mutect2, varscan2
- NPR2 | c.2402T>C p.L801P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61042093; called by muse, mutect2, varscan2
- NRK | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54602310; called by muse, mutect2, varscan2
- NRXN2 | c.3109G>A p.G1037R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55459510; called by muse, mutect2, varscan2
- NWD1 | c.3004C>T p.P1002S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV60347693; called by muse, mutect2, varscan2
- NXPH2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55645209; called by muse, mutect2, varscan2
- NYAP2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs866667390, COSV56002681; called by mutect2, varscan2
- OAS3 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV57447753; called by muse, mutect2, varscan2
- OGT | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65481987; called by muse, mutect2, varscan2
- OR4C12 | c.842A>T p.N281I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV58860664; called by muse, mutect2, varscan2
- OR4C15 | c.881G>A p.G294E (on ENST00000314644; = p.G240E on NM_001001920.2) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV58954441; called by muse, mutect2, varscan2
- OR4K5 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs567087443, COSV100262396, COSV60003289; called by muse, mutect2, varscan2
- OR51A4 | c.889A>C p.T297P | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV66749835; called by muse, mutect2
- OR51A7 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs906070592, COSV63788359; called by mutect2, varscan2
- OR51B4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66517518; called by muse, mutect2, varscan2
- OR51E2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs867888582, COSV67806638; called by mutect2, varscan2
- OR51E2 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs781672647, COSV67808237; called by muse, mutect2, varscan2
- OR51S1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs538018962, COSV59057539; called by muse, mutect2, varscan2
- OR6Y1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV56930508; called by muse, mutect2, varscan2
- OR8H2 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.612); catalogued as COSV57946566; called by muse, mutect2, varscan2
- OR8K5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57890146; called by muse, varscan2
- OTOF | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55511649; called by mutect2, varscan2
- PAPPA2 | c.4211C>T p.A1404V | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV62794747; called by muse, mutect2, varscan2
- PARP12 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54936005; called by mutect2, varscan2
- PATJ | c.3630T>A p.D1210E | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57167620; called by muse, mutect2, varscan2
- PAX2 | c.755G>A p.R252Q (on ENST00000428433 / NM_003987.5; = p.R229Q on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs753350907, COSV62291325; called by muse, mutect2, varscan2
- PCARE | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV59056506; called by mutect2, varscan2
- PCDH15 | c.5333C>T p.S1778L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.02); catalogued as rs778249393, COSV64716444, COSV64750519; called by mutect2, varscan2
- PCDHA7 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.581); catalogued as rs781874568, COSV65346179; called by muse, mutect2, varscan2
- PCDHB12 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.521); catalogued as rs782400979, COSV53399192; called by muse, mutect2, varscan2
- PCDHB5 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV50650088; called by muse, mutect2, varscan2
- PCDHB5 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.364); catalogued as COSV50652824; called by muse, varscan2
- PCDHGB2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.029); catalogued as rs765885822, COSV53995660; called by muse, mutect2, varscan2
- PCLO | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); catalogued as COSV61652778; called by muse, mutect2, varscan2
- PCOLCE2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as rs139818603, COSV55997971; called by mutect2, varscan2
- PDPR | c.887G>A p.W296* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV55354567; called by mutect2, varscan2
- PELI3 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1320405511; called by mutect2, varscan2
- PHEX | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.227); catalogued as COSV65077494; called by muse, mutect2, varscan2
- PHF10 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1157738884, COSV59322348, COSV59323618; called by muse, mutect2, varscan2
- PHKA1 | c.3184G>A p.G1062R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59808824; called by muse, varscan2
- PIK3AP1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV59534942; called by muse, mutect2, varscan2
- PIK3CG | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.151); catalogued as rs762805000, COSV63245782; called by mutect2, varscan2
- PKD1L2 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs766516370, COSV55166396; called by mutect2, varscan2
- PKD1L2 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); catalogued as COSV61417844; called by muse, mutect2, varscan2
- PKP2 | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216433436, COSV50739679; ClinVar: uncertain significance; called by muse, mutect2
- PLCB4 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53794447; called by muse, varscan2
- PMS2 | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56222768; called by muse, mutect2, varscan2
- POP1 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV62893703; called by muse, mutect2, varscan2
- PPEF1 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs753315042, COSV62996289; called by mutect2, varscan2
- PPP1R9A | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56888117, COSV56902956; called by muse, mutect2, varscan2
- PPP2R3A | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as rs1333096177, COSV53860206; called by mutect2, varscan2
- PRAME | c.1232T>C p.L411S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV67162184; called by muse, mutect2, varscan2
- PRB2 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.071); catalogued as COSV66983822; called by muse, mutect2
- PRF1 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs911803198, COSV100942709, COSV64615446; called by muse, mutect2, varscan2
- PRKAB2 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54214109; called by muse, mutect2, varscan2
- PRMT3 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV58176718, COSV58179249; called by muse, mutect2, varscan2
- PRUNE2 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as COSV65042917, COSV65044699; called by muse, mutect2, varscan2
- PSG11 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100106344, COSV60456784; called by muse, mutect2, varscan2
- PSG6 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 109/336 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs865872575, COSV51835669; called by muse, mutect2, varscan2
- PSPH | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV51909066; called by muse, mutect2, varscan2
- PTH1R | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100480982; called by muse, mutect2, varscan2
- PTPRT | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs724159835, COSV61966941; called by mutect2, varscan2
- R3HDM1 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99926277; called by muse, mutect2, varscan2
- RAPGEF1 | c.3223G>C p.E1075Q | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.993); catalogued as COSV64701117; called by muse, mutect2, varscan2
- RBAK | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | catalogued as rs1420105218, COSV100806676; called by mutect2, varscan2
- RBM6 | c.3334C>T p.R1112* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV56481082; called by mutect2, varscan2
- RELB | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1469761737, COSV55511891; called by muse, mutect2, varscan2
- RFX3 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56521319; called by mutect2, varscan2
- RHPN2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54282290; called by muse, mutect2, varscan2
- RIF1 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV54621167; called by muse, mutect2, varscan2
- RNF128 | c.704G>A p.R235Q (on ENST00000255499 / NM_194463.2; = p.R209Q on NM_024539.3) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.947); catalogued as rs751877459, COSV55253095; called by muse, mutect2, varscan2
- RNH1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV62251499, COSV62251602; called by muse, mutect2, varscan2
- ROBO1 | c.3749C>T p.P1250L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV71396434; called by muse, mutect2, varscan2
- ROBO4 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV60626344; called by muse, mutect2, varscan2
- RP1 | c.3352C>T p.H1118Y | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55111043; called by muse, mutect2, varscan2
- RTL4 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV61206970; called by muse, mutect2, varscan2
- RXFP1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV57053832; called by mutect2, varscan2
- RYR1 | c.8005G>A p.E2669K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62104483; called by muse, mutect2, varscan2
- RYR1 | c.9003C>T p.I3001= | Splice Region (SNP) | VAF 60/275 reads (22%) | catalogued as COSV62104488; called by muse, varscan2
- SAFB | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as COSV52652935; called by muse, mutect2, varscan2
- SALL4 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV53854539; called by muse, mutect2, varscan2
- SALL4 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1245259397, COSV53854623; called by mutect2, varscan2
- SAMD9L | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs773949455, COSV59083682; called by mutect2, varscan2
- SCEL | c.1073C>T p.P358L (on ENST00000349847 / NM_144777.3; = p.P338L on NM_003843.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.139); catalogued as rs748682440, COSV62994146; called by muse, mutect2, varscan2
- SCN2A | c.5705G>A p.R1902H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs747710683, COSV51849749, COSV99333166; ClinVar: uncertain significance; called by mutect2, varscan2
- SCN7A | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69269335; called by muse, mutect2, varscan2
- SCNN1G | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55600689; called by muse, mutect2, varscan2
- SCUBE3 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.878); catalogued as rs1040883668, COSV51458240; called by muse, mutect2, varscan2
- SDC1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as rs375790781, COSV54339735; called by muse, mutect2, varscan2
- SDR42E1 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1310752254, COSV61094791; called by muse, mutect2, varscan2
- SELP | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV55255536; called by muse, mutect2, varscan2
- SEMA5B | c.992T>G p.L331R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs745447561, COSV52103856; called by mutect2, varscan2
- SERPINB6 | c.736G>A p.E246K (on ENST00000612421 / NM_001271823.2; = p.E227K on NM_004568.6) | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs1201327476, COSV59566643; called by muse, mutect2, varscan2
- SETD3 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59285937; called by mutect2, varscan2
- SFMBT1 | c.2204A>G p.K735R | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.757); catalogued as COSV56255953; called by muse, mutect2, varscan2
- SIGLEC11 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs201115105, COSV101389393; called by muse, varscan2
- SIGLEC11 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.411); catalogued as rs550434699, COSV70221929; called by muse, varscan2
- SIGLEC7 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV58317077; called by mutect2, varscan2
- SKP2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as COSV57043645; called by muse, mutect2, varscan2
- SLC18A1 | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); catalogued as COSV52350072; called by muse, mutect2, varscan2
- SLC27A2 | c.1379A>T p.Y460F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV51061028; called by muse, mutect2, varscan2
- SLC35C1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as rs1217987912, COSV58480545; called by muse, mutect2, varscan2
- SLC39A12 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV66200973; called by muse, mutect2, varscan2
- SLC4A1 | c.2567C>T p.S856F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419411396, COSV52261875; called by muse, mutect2, varscan2
- SLC7A13 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867805359, COSV52534817, COSV99879296; called by muse, mutect2
- SLC9A2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV52135245, COSV99296549; called by muse, mutect2, varscan2
- SLIT2 | c.2645G>A p.G882E | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56585204; called by muse, mutect2, varscan2
- SMAGP | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.298); catalogued as COSV66313123; called by muse, mutect2, varscan2
- SMCHD1 | c.5308C>T p.R1770C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55263921; called by mutect2, varscan2
- SMOC2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100635116; called by muse, mutect2, varscan2
- SNCAIP | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs773989411, COSV54405243; called by muse, mutect2, varscan2
- SPATA22 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52153695; called by muse, mutect2, varscan2
- SPESP1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52993143; called by muse, mutect2, varscan2
- SPIC | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100162971; called by muse, mutect2, varscan2
- SPTLC2 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53641873; called by muse, varscan2
- SRGAP3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV64536826; called by muse, mutect2, varscan2
- SRPX2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV100884032; called by mutect2, varscan2
- ST8SIA4 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | PolyPhen benign (0); catalogued as COSV51513636; called by muse, mutect2, varscan2
- STXBP5L | c.3317G>A p.G1106E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV56502748; called by muse, mutect2, varscan2
- SUPT4H1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV56643289; called by muse, mutect2, varscan2
- SYN3 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60512952, COSV60514575; called by muse, mutect2, varscan2
- SYNDIG1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV65234813; called by muse, mutect2, varscan2
- SYNE1 | c.15746C>T p.T5249I (on ENST00000367255 / NM_182961.4; = p.T5178I on NM_033071.3) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99566150; called by muse, mutect2, varscan2
- SYNE1 | c.15745A>T p.T5249S (on ENST00000367255 / NM_182961.4; = p.T5178S on NM_033071.3) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99566162; called by muse, mutect2, varscan2
- SYT1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54032324; called by muse, mutect2, varscan2
- SYT3 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58898062; called by muse, mutect2, varscan2
- SYT5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62830957; called by muse, mutect2, varscan2
- TAC3 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100269869; called by muse, mutect2, varscan2
- TACR3 | c.1303A>G p.S435G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV59201954, COSV59205646; called by muse, mutect2, varscan2
- TBCCD1 | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58662909; called by muse, mutect2, varscan2
- TBL1X | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV54284791; called by muse, mutect2, varscan2
- TBX4 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748587793, COSV53607761; called by muse, mutect2, varscan2
- TDO2 | c.1158C>A p.H386Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs771641094, COSV101467856; called by muse, mutect2, varscan2
- TDP1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV59642364; called by mutect2, varscan2
- TEKT3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV58628784; called by muse, mutect2, varscan2
- TEKT4 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV54626919; called by muse, mutect2, varscan2
- TENM1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1377426701, COSV100949397, COSV64447172; called by muse, mutect2, varscan2
- TENM1 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs778366638, COSV100948843, COSV100950147; called by mutect2, varscan2
- TENT2 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57138429; called by muse, mutect2, varscan2
- TEP1 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52996705; called by muse, mutect2, varscan2
- THOC2 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55551621, COSV55553778; called by muse, varscan2
- THSD7B | c.4417C>T p.R1473W (on ENST00000272643; = p.R1471W on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs368781810, COSV99755798; called by mutect2, varscan2
- TLE6 | c.1558G>A p.G520R (on ENST00000246112 / NM_001143986.2; = p.G397R on NM_024760.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1368059556, COSV53581855; called by muse, mutect2, varscan2
- TMCO4 | c.876C>T p.Y292= | Splice Region (SNP) | VAF 22/125 reads (18%) | catalogued as COSV53875289; called by muse, varscan2
- TMEM45A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60254857; called by muse, mutect2, varscan2
- TMPRSS3 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs767019311, COSV52305503; called by muse, mutect2, varscan2
- TNIP3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV50251354; called by muse, mutect2, varscan2
- TNXB | c.10481C>T p.S3494F (on ENST00000647633; = p.S3247F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757839364, COSV64478541; called by muse, mutect2, varscan2
- TPR | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV66603419; called by muse, mutect2, varscan2
- TPRG1L | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs866026568, COSV99573328; called by muse, mutect2, varscan2
- TRANK1 | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57158429; called by muse, mutect2, varscan2
- TRBV29-1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1265856260; called by mutect2, varscan2
- TRHDE | c.2520G>A p.W840* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs761399970, COSV53840273, COSV53856355; called by mutect2, varscan2
- TRIM2 | c.2180T>C p.V727A (on ENST00000437508; = p.V754A on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58636804; called by muse, mutect2, varscan2
- TRIO | c.6629C>T p.P2210L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750016484, COSV60085857, COSV60089657; called by mutect2, varscan2
- TRPV6 | c.1869G>C p.W623C | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63892835; called by muse, mutect2, varscan2
- TRRAP | c.10046C>T p.S3349F (on ENST00000359863 / NM_001244580.1; = p.S3320F on NM_003496.3) | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV62850534; called by muse, mutect2, varscan2
- TTN | c.67513C>T p.P22505S (on ENST00000591111; = p.P15081S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | PolyPhen probably damaging (0.923); catalogued as COSV60219705; called by muse, mutect2, varscan2
- TTN | c.46526C>T p.P15509L (on ENST00000591111; = p.P8085L on NM_003319.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | PolyPhen probably damaging (0.999); catalogued as rs764792715, COSV60219750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.43216G>A p.E14406K (on ENST00000591111; = p.E6982K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | PolyPhen possibly damaging (0.84); catalogued as COSV59863108; called by muse, mutect2, varscan2
- TTN | c.25073C>T p.S8358F (on ENST00000591111; = p.S7431F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | PolyPhen possibly damaging (0.508); catalogued as rs868429008, COSV59912055; called by muse, mutect2, varscan2
- TTN | c.22990C>T p.R7664W (on ENST00000591111; = p.R6737W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | PolyPhen possibly damaging (0.9); catalogued as rs1227497572, COSV60158883; called by mutect2, varscan2
- TTN | c.22757G>A p.G7586E (on ENST00000591111; = p.G6659E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | PolyPhen probably damaging (0.974); catalogued as rs1362459833, COSV60219834; called by muse, mutect2, varscan2
- TTN | c.3727C>T p.Q1243* (on ENST00000591111; = p.Q1197* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV60219856; called by mutect2, varscan2
- TUBB6 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as rs1400406544, COSV52316353; called by muse, mutect2, varscan2
- UBN1 | c.567+2T>C p.X189_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV52170740; called by muse, mutect2, varscan2
- UGT2A1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV54139511; called by muse, mutect2, varscan2
- UGT2B28 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs774566784, COSV59433458; called by mutect2, varscan2
- UNC45B | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52092402, COSV99268713; called by muse, varscan2
- USHBP1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV52244683; called by muse, mutect2, varscan2
- USP33 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100657033, COSV62470675; called by muse, mutect2, varscan2
- USP8 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV56166558; called by muse, varscan2
- UTRN | c.1247A>T p.H416L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839959; called by muse, mutect2, varscan2
- VCPIP1 | c.2184G>C p.Q728H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60049270; called by muse, mutect2, varscan2
- VCX3B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV101123791; called by muse, varscan2
- VPS13A | c.8084A>C p.H2695P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100652893; called by muse, varscan2
- WDR49 | c.657G>A p.W219* (on ENST00000308378 / NM_001366158.1; = p.W560* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV57708693; called by muse, mutect2, varscan2
- WFS1 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs763561068, COSV56990499; called by muse, mutect2
- WWC1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs78544296, COSV54655402; called by muse, mutect2, varscan2
- XDH | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149508779, COSV65150145; called by muse, mutect2, varscan2
- XIRP2 | c.2807C>T p.S936L (on ENST00000628543; = p.S1111L on NM_152381.6) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs771644507, COSV54695141; called by mutect2, varscan2
- YLPM1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53117081; called by mutect2, varscan2
- YLPM1 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV53117091; called by muse, mutect2, varscan2
- ZC3H6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV59669585; called by muse, mutect2, varscan2
- ZFAND4 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58897825; called by muse, varscan2
- ZFAND6 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55713026; called by muse, mutect2, varscan2
- ZIM3 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV54144783; called by muse, mutect2, varscan2
- ZMAT1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV65659506; called by muse, mutect2, varscan2
- ZNF142 | c.3017C>T p.A1006V (on ENST00000411696 / NM_001379660.1; = p.A806V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as rs754018488, COSV68744743; called by muse, mutect2, varscan2
- ZNF208 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1272718549, COSV68110288; called by muse, mutect2, varscan2
- ZNF530 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV60532140; called by muse, mutect2, varscan2
- ZNF534 | c.286G>A p.E96K (on ENST00000332323 / NM_001143939.3; = p.E83K on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.971); catalogued as COSV56519563; called by muse, mutect2, varscan2
- ZNF566 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776067169, COSV67574296; called by mutect2, varscan2
- ZNF577 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV56817077; called by muse, mutect2, varscan2
- ZNF662 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV60243270; called by muse, mutect2, varscan2
- ZNF804A | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs750195715, COSV56440604, COSV56454409; called by mutect2, varscan2
- ZNF835 | c.725G>C p.R242P | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73379606, COSV73379622; called by muse, mutect2, varscan2
- AGAP3 | c.1256del p.L419Rfs*6 (on ENST00000622464; = p.L455Rfs*6 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel*, varscan2
- COL2A1 | c.3111+2_3111+3del p.X1037_splice | Splice Site (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- HNF1B | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR51G1 | c.254_264del p.G85Vfs*2 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC1A | c.2857_2860del p.E953Rfs*10 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | called by mutect2, pindel, varscan2
- THEMIS | c.650_653del p.K217Tfs*6 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by pindel, varscan2
- TRAV29DV5 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TRDC | c.2G>A p.*1= | Missense Mutation (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- ABCC10 | c.3975C>T p.I1325= (on ENST00000372530 / NM_001198934.2; = p.I1297= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV55091716; called by muse, varscan2
- ABI3BP | c.270G>A p.P90= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs376689184; called by mutect2, varscan2
- ADAMTS10 | c.1293C>T p.F431= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs782470220, COSV54357211; called by muse, mutect2, varscan2
- ADPRH | c.762G>A p.R254= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs780234725, COSV63695470; called by muse, mutect2, varscan2
- AK7 | c.1008G>A p.E336= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV50869549; called by muse, mutect2, varscan2
- AMHR2 | c.1215C>T p.L405= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57686461; called by muse, mutect2, varscan2
- ANKRD50 | c.3582T>C p.T1194= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV72386008; called by muse, mutect2
- AOC3 | c.297G>A p.V99= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV53827983; called by muse, mutect2, varscan2
- ARHGAP12 | c.267T>C p.N89= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV60965091; called by muse, mutect2, varscan2
- ARID1A | c.1632C>T p.H544= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as rs772448072, COSV61383992, COSV61391080; called by muse, mutect2, varscan2
- ARID3C | c.1203A>C p.P401= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52408300; called by muse, mutect2, varscan2
- ATXN7 | c.1125C>T p.V375= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as COSV55753820; called by muse, mutect2, varscan2
- BBX | c.1362G>A p.K454= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1453695911, COSV57890345; called by muse, mutect2, varscan2
- BCL9L | c.2955C>T p.V985= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV52687392; called by muse, mutect2, varscan2
- BEST2 | c.486T>C p.F162= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV50372429; called by muse, mutect2, varscan2
- C12orf60 | c.402G>A p.G134= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV99966912; called by muse, mutect2
- CACHD1 | c.3258C>T p.I1086= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV51557369; called by mutect2, varscan2
- CACNA1B | c.4221C>T p.F1407= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs201003634; called by mutect2, varscan2
- CACNA2D3 | c.2298C>T p.F766= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV55525892; called by muse, mutect2, varscan2
- CACNG2 | c.126C>T p.T42= | Silent (SNP) | VAF 46/329 reads (14%) | catalogued as rs147878619; called by muse, mutect2, varscan2
- CAMK2D | c.1371C>T p.R457= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV56435607; called by muse, mutect2, varscan2
- CBLB | c.1449C>T p.S483= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV51432569; called by muse, mutect2, varscan2
- CCDC30 | c.1884G>A p.T628= (on ENST00000340612; = p.T585= on NM_001080850.3) | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs1313009985, COSV59608282; called by muse, mutect2, varscan2
- CCNF | c.555C>T p.S185= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV53541807; called by muse, mutect2, varscan2
- CD5 | c.159G>A p.K53= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100759823; called by muse, mutect2, varscan2
- CDH6 | c.2145C>T p.F715= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54065375; called by mutect2, varscan2
- CFTR | c.2679G>A p.G893= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as CS021743, COSV50070370, COSV50077065; called by muse, varscan2
- CIITA | c.870C>T p.F290= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs546955314, COSV60860093; called by mutect2, varscan2
- CLVS1 | c.735G>A p.R245= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV57971824; called by muse, mutect2, varscan2
- CNTN1 | c.1272C>T p.I424= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV61643026; called by muse, mutect2, varscan2
- COL4A4 | c.2502G>A p.G834= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV61632280; called by muse, mutect2, varscan2
- COP1 | c.345C>T p.L115= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1415578588, COSV100443363; called by mutect2, varscan2
- CPNE7 | c.1824G>A p.E608= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV52015595; called by muse, varscan2
- CSMD1 | c.3909C>T p.L1303= (on ENST00000520002; = p.L1302= on NM_033225.6) | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as COSV59355468; called by muse, mutect2, varscan2
- CTXN3 | c.147C>T p.F49= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV65218652; called by muse, mutect2, varscan2
- CUX2 | c.945G>A p.K315= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV55641346; called by muse, mutect2, varscan2
- CWH43 | c.1935C>T p.I645= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV56940696; called by muse, mutect2, varscan2
- CYP2C19 | c.132G>A p.Q44= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV64908674; called by muse, mutect2, varscan2
- CYP2F1 | c.1206C>T p.F402= | Silent (SNP) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- CYTIP | c.900G>A p.R300= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV51634957; called by muse, mutect2, varscan2
- DENND2C | c.1305G>A p.K435= (on ENST00000393274 / NM_001256404.2; = p.K378= on NM_198459.4) | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV67923060; called by muse, mutect2, varscan2
- DENND5A | c.2622C>T p.I874= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs373547821; called by mutect2, varscan2
- DGCR2 | c.990C>T p.F330= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs1371160566, COSV54217043; called by mutect2, varscan2
- DLX5 | c.369C>T p.T123= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV56033745; called by muse, mutect2, varscan2
- DNAH10 | c.1434G>A p.A478= (on ENST00000409039; = p.A417= on NM_207437.3) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs764312185, COSV101292301; called by mutect2, varscan2
- DNAH10 | c.5094G>A p.V1698= (on ENST00000409039; = p.V1637= on NM_207437.3) | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as COSV68988567; called by muse, mutect2, varscan2
- DNAH9 | c.7998C>T p.F2666= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV52335485; called by muse, mutect2, varscan2
- DRG2 | c.657C>T p.F219= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV56728905; called by muse, mutect2, varscan2
- DSC3 | c.456C>T p.F152= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV64574280; called by muse, mutect2, varscan2
- DSP | c.6132C>T p.S2044= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV65793666; called by muse, mutect2, varscan2
- EIF2B1 | c.228C>T p.I76= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV57458414, COSV57459564; called by mutect2, varscan2
- ELOA2 | c.696G>A p.Q232= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1170739754, COSV55304094; called by mutect2, varscan2
- ENTPD3 | c.636G>A p.V212= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1355704182, COSV57195601; called by muse, mutect2, varscan2
- EPHA10 | c.564C>T p.F188= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1403549965, COSV57625722; called by muse, mutect2, varscan2
- EPHA4 | c.1584G>A p.L528= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV56039681; called by muse, mutect2, varscan2
- EPPK1 | c.5457C>T p.A1819= | Silent (SNP) | VAF 88/178 reads (49%) | catalogued as COSV73262024; called by muse, mutect2, varscan2
- ERAL1 | c.696C>T p.V232= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1438402745, COSV54740547; called by muse, mutect2, varscan2
- ERC2 | c.1032G>A p.V344= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs1031350431, COSV55611741; called by mutect2, varscan2
- ESRP1 | c.915C>T p.F305= | Silent (SNP) | VAF 70/784 reads (9%) | catalogued as COSV64411605; called by muse, mutect2
- F8 | c.5209C>T p.L1737= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100811688, COSV64271136, COSV64276619; called by muse, mutect2, varscan2
- F8 | c.1398A>G p.G466= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV64276633; called by muse, mutect2, varscan2
- FAM107B | c.153C>T p.T51= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs746804750, COSV51689646; called by muse, mutect2, varscan2
- FAM110B | c.924C>T p.F308= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV64066824; called by muse, mutect2, varscan2
- FAM90A1 | c.234G>A p.G78= | Silent (SNP) | VAF 18/223 reads (8%) | catalogued as COSV100274330; called by muse, mutect2
- FARS2 | c.1092C>T p.I364= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs754931472, COSV51171903; called by mutect2, varscan2
- FLT3 | c.393G>A p.L131= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV54049623, COSV54062894; called by mutect2, varscan2
- FMNL2 | c.2214G>C p.R738= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as COSV56500221, COSV99980039; called by muse, mutect2, varscan2
- FOXL2NB | c.145C>T p.L49= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs377658501, COSV57728910; called by mutect2, varscan2
- FSD1 | c.1419G>A p.Q473= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV55697975; called by muse, mutect2, varscan2
- GAS2L1 | c.1653C>T p.P551= | Silent (SNP) | VAF 79/214 reads (37%) | catalogued as rs1260521240, COSV53330066; called by muse, mutect2, varscan2
- GATA4 | c.810C>T p.S270= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100632950, COSV58732431, COSV58734910; called by muse, varscan2
- GBA2 | c.1504C>T p.L502= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100803549, COSV62306500; called by muse, mutect2, varscan2
- GBA3 | c.867C>T p.F289= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101545557, COSV72438460; called by mutect2, varscan2
- GCDH | c.639C>T p.I213= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53367568; called by mutect2, varscan2
- GID8 | c.123C>T p.G41= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV56611993; called by muse, mutect2, varscan2
- GLG1 | c.1983G>A p.Q661= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as COSV52671416; called by muse, varscan2
- GLRA3 | c.396C>T p.F132= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV56857610, COSV56862555; called by muse, mutect2, varscan2
- GPR17 | c.501C>T p.S167= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs754180682, COSV55756418; called by muse, mutect2, varscan2
- GPR179 | c.5046G>A p.V1682= (on ENST00000621958; = p.V1681= on NM_001004334.4) | Silent (SNP) | VAF 38/127 reads (30%) | called by muse, varscan2
- GPT2 | c.684C>T p.A228= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs1175793000, COSV60839524; called by muse, mutect2, varscan2
- GPX6 | c.474G>A p.P158= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs1234071872, COSV62657158; called by muse, mutect2, varscan2
- GRIN3A | c.3000G>T p.V1000= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV62456469; called by mutect2, varscan2
- GRM6 | c.2118C>T p.S706= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1405668351, COSV51441285; called by muse, mutect2
- GSPT1 | c.1212C>T p.S404= (on ENST00000420576 / NM_001130007.2; = p.S542= on NM_002094.4) | Silent (SNP) | VAF 59/223 reads (26%) | catalogued as COSV70452876; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2424C>T p.T808= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV63100641; called by muse, varscan2
- H6PD | c.1563C>T p.F521= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV66231717; called by muse, mutect2, varscan2
- HAPLN1 | c.231C>T p.I77= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV57148922, COSV57150371; called by muse, mutect2, varscan2
- HK3 | c.2505G>A p.R835= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52839604; called by muse, mutect2, varscan2
- HMGCL | c.150C>T p.I50= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs376705029; called by mutect2, varscan2
- HMGCS2 | c.909C>T p.P303= | Silent (SNP) | VAF 207/445 reads (47%) | catalogued as COSV65568712; called by muse, mutect2, varscan2
- IGSF10 | c.1374C>T p.I458= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV56789209; called by muse, mutect2, varscan2
- INSR | c.1677A>T p.V559= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as COSV57168732; called by mutect2, varscan2
- ITGAM | c.768C>T p.I256= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54940063; called by mutect2, varscan2
- KCNH5 | c.1413C>T p.F471= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV59769482; called by muse, mutect2, varscan2
- KCNT1 | c.1401C>T p.P467= (on ENST00000488444; = p.P486= on NM_020822.3) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53706728; called by muse, mutect2, varscan2
- KDM5C | c.714C>T p.I238= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV64767282; called by muse, mutect2, varscan2
- KEL | c.1932C>T p.I644= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs1054734931, COSV62336678; called by mutect2, varscan2
- KLB | c.1512A>G p.R504= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV57303643; called by muse, mutect2, varscan2
- KLK1 | c.291A>G p.P97= | Silent (SNP) | VAF 24/267 reads (9%) | catalogued as COSV56827762; called by muse, mutect2
- KLRC1 | c.222G>A p.G74= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV61725617; called by muse, mutect2, varscan2
- KLRC3 | c.675C>T p.I225= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs764883652, COSV67251105; called by mutect2, varscan2
- KMT2A | c.2046C>T p.L682= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs782271167, COSV63290052; called by muse, mutect2, varscan2
- KMT2D | c.7416C>G p.P2472= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV56467721; called by muse, mutect2, varscan2
- KMT5B | c.397A>C p.R133= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV58568445; called by muse, mutect2, varscan2
- KRT25 | c.1335G>A p.E445= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV56445933; called by muse, mutect2, varscan2
- KRT82 | c.1335C>T p.S445= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV57785418; called by muse, mutect2
- KSR2 | c.2013C>T p.L671= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56678914; called by mutect2, varscan2
- LILRA5 | c.855G>A p.Q285= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV56643217; called by muse, mutect2, varscan2
- LRP1B | c.4386C>T p.I1462= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV67221314; called by mutect2, varscan2
- LSM3 | c.270T>C p.D90= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV60044210; called by muse, mutect2, varscan2
- LYST | c.8019A>C p.V2673= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as COSV67711007; called by muse, mutect2, varscan2
- MAGEA10 | c.921G>A p.R307= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as COSV54882812, COSV99726816; called by muse, mutect2, varscan2
- MDFI | c.123C>T p.S41= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV57822513; called by muse, mutect2, varscan2
- MECR | c.348C>G p.G116= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV55286638, COSV55286738; called by muse, mutect2, varscan2
- MEPE | c.219C>A p.S73= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100734955; called by mutect2, varscan2
- MET | c.1398G>A p.V466= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as rs779091695, COSV59265616; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MIDEAS | c.87C>T p.P29= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs371711282, COSV54093739, COSV54097198; called by muse, mutect2, varscan2
- MMP26 | c.108C>T p.F36= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV56173306; called by mutect2, varscan2
- MUC16 | c.22227C>T p.S7409= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1430151257, COSV67444063, COSV67480979; called by muse, varscan2
- MXD1 | c.354A>G p.Q118= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as COSV52480416; called by muse, mutect2, varscan2
- MYO5B | c.2185C>T p.L729= | Silent (SNP) | VAF 23/194 reads (12%) | catalogued as COSV99545158; called by muse, mutect2, varscan2
- NAV2 | c.2952C>T p.S984= (on ENST00000396087 / NM_001244963.2; = p.S961= on NM_145117.5) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1211781729, COSV60662634; called by muse, mutect2, varscan2
- NFIX | c.903C>T p.S301= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV62179036, COSV62181527; called by muse, mutect2, varscan2
- NKD1 | c.1125C>T p.I375= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99194054; called by mutect2, varscan2
- NLRP8 | c.3102C>A p.P1034= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs142444217; called by muse, mutect2, varscan2
- NOL6 | c.3057C>T p.I1019= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs763517037, COSV53044349; called by muse, mutect2, varscan2
- NOX5 | c.168G>A p.V56= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV52993151; called by mutect2, varscan2
- NOXA1 | c.1377C>T p.F459= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as rs779221910, COSV58162959; called by muse, mutect2, varscan2
- NPAP1 | c.1584C>T p.S528= | Silent (SNP) | VAF 37/166 reads (22%) | catalogued as COSV100274913, COSV61509504; called by muse, mutect2, varscan2
- NPBWR2 | c.621C>T p.V207= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV63900393; called by muse, mutect2, varscan2
- NPL | c.747C>T p.I249= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV51125600; called by muse, mutect2, varscan2
- NPR3 | c.1158G>A p.G386= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as rs943903938, COSV54087891, COSV54088396; called by muse, mutect2, varscan2
- NYNRIN | c.4152C>T p.L1384= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV66843875; called by muse, mutect2, varscan2
- OIT3 | c.1287G>A p.L429= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100468017; called by muse, mutect2, varscan2
- OR10A3 | c.711C>T p.A237= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV62459893; called by muse, mutect2, varscan2
- OR1J4 | c.879G>A p.R293= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV61589852; called by muse, mutect2, varscan2
- OR2F2 | c.924C>T p.F308= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs371372563, COSV68833119; called by muse, mutect2, varscan2
- OR4E2 | c.927G>A p.T309= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs975852343, COSV57731591; called by mutect2, varscan2
- OR51B6 | c.60G>A p.K20= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV66513159; called by muse, mutect2, varscan2
- OR51Q1 | c.90C>T p.S30= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV56179957; called by muse, mutect2, varscan2
- OR51V1 | c.858C>T p.F286= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs769935079, COSV100343588, COSV58314294; called by mutect2, varscan2
- OR51V1 | c.33G>A p.T11= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs550954546, COSV58314225; called by mutect2, varscan2
- OR52A5 | c.714C>T p.F238= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56616082; called by mutect2, varscan2
- OR5AS1 | c.891G>A p.V297= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1565026622, COSV57982068; called by mutect2, varscan2
- OR5F1 | c.894G>A p.K298= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53547749; called by muse, mutect2, varscan2
- OR5L1 | c.753C>T p.F251= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1381189325, COSV61734552, COSV61735291, COSV61735761; called by muse, mutect2, varscan2
- OR5M11 | c.255C>T p.I85= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs748126869, COSV73141645; called by mutect2, varscan2
- OR6K2 | c.291C>T p.L97= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs142441693, COSV62743473; called by muse, mutect2, varscan2
- OR6T1 | c.205C>T p.L69= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs1272609405, COSV58308502; called by muse, mutect2, varscan2
- OR8K3 | c.108G>A p.V36= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV57132355; called by mutect2, varscan2
- OTOA | c.564A>T p.S188= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV53760160; called by muse, mutect2, varscan2
- P3H4 | c.1056C>T p.P352= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV62680161; called by muse, mutect2, varscan2
- PAFAH2 | c.150C>T p.P50= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV65339867; called by muse, mutect2, varscan2
- PAICS | c.1134T>G p.L378= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV51709486; called by muse, mutect2, varscan2
- PCDHA12 | c.144C>T p.I48= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV56529348; called by mutect2, varscan2
- PCLO | c.9078T>C p.T3026= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV61652767; called by muse, mutect2, varscan2
- PDE3A | c.3312G>A p.L1104= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs897928436, COSV100761759, COSV62978849; called by muse, mutect2, varscan2
- PDHA2 | c.220T>C p.L74= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs1460857977, COSV54780671; called by muse, mutect2, varscan2
- PELI3 | c.399C>T p.S133= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100291788; called by muse, mutect2, varscan2
- PEX26 | c.783C>T p.I261= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as COSV61604953; called by muse, mutect2, varscan2
- PGAP4 | c.1167G>A p.G389= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV66388131; called by muse, mutect2, varscan2
- PIBF1 | c.1212A>G p.E404= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as COSV58326294; called by muse, mutect2, varscan2
- PKD2L1 | c.705C>T p.L235= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV58397720; called by muse, mutect2, varscan2
- PLXNA3 | c.2058C>T p.I686= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV63754916; called by muse, mutect2, varscan2
- POTEE | c.2439G>A p.K813= | Silent (SNP) | VAF 41/217 reads (19%) | catalogued as rs764520721, COSV58224999; called by muse, mutect2, varscan2
- PPM1L | c.852C>T p.I284= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs1398869026, COSV55568070; called by muse, mutect2, varscan2
- PRAMEF20 | c.1242C>T p.A414= | Silent (SNP) | VAF 93/351 reads (26%) | called by muse, mutect2, varscan2
- PRKACG | c.552G>A p.T184= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55252209, COSV55253585; called by mutect2, varscan2
- PRRT3 | c.777G>A p.E259= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV55978074; called by muse, mutect2, varscan2
- PSG7 | c.453C>T p.I151= | Silent (SNP) | VAF 60/167 reads (36%) | catalogued as COSV68445009; called by muse, mutect2, varscan2
- PTPRZ1 | c.2808C>T p.S936= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV66442089; called by muse, mutect2, varscan2
- REG1B | c.24C>T p.F8= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs868243041, COSV59304536; called by mutect2, varscan2
- RPAP1 | c.3259C>T p.L1087= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs556819755, COSV58541187; called by muse, mutect2, varscan2
- RPAP1 | c.1851C>T p.P617= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV58541195; called by muse, mutect2, varscan2
- RTL4 | c.67C>T p.L23= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV61206964; called by muse, mutect2, varscan2
- RTTN | c.4812A>G p.K1604= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV55348990; called by muse, mutect2, varscan2
- S1PR1 | c.780C>T p.I260= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs267597895, COSV59512780; called by muse, mutect2, varscan2
- SAFB | c.2721C>T p.S907= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs752305894, COSV52652789; called by mutect2, varscan2
- SCN5A | c.12C>T p.F4= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV60067643; called by muse, mutect2, varscan2
- SDC1 | c.726C>T p.A242= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV54340888; called by muse, mutect2, varscan2
- SEMG2 | c.843G>C p.R281= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV65647691, COSV65647756; called by muse, mutect2, varscan2
- SERPINB7 | c.606G>A p.G202= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV60535055; called by muse, mutect2, varscan2
- SERPINI1 | c.885C>T p.F295= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV55513094; called by mutect2, varscan2
- SIGLEC6 | c.1110G>A p.V370= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV58434986; called by muse, varscan2
- SIGLEC9 | c.1101C>T p.F367= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as rs1216871783, COSV51584528; called by mutect2, varscan2
- SKAP1 | c.963C>T p.I321= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV61149694; called by muse, mutect2, varscan2
- SLC12A7 | c.1353C>T p.I451= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV53760112; called by muse, mutect2, varscan2
- SLC15A2 | c.213C>T p.F71= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as rs200627431, COSV55199645; called by muse, mutect2, varscan2
- SLC1A3 | c.1398G>A p.T466= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs140281779; called by mutect2, varscan2
- SLC22A18 | c.1000C>T p.L334= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV56541052; called by muse, mutect2, varscan2
- SLC44A1 | c.364C>T p.L122= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs376729977; called by muse, mutect2, varscan2
- SLC4A11 | c.1674C>T p.A558= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV66261683; called by muse, mutect2, varscan2
- SLC4A8 | c.1575C>T p.S525= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV60656228; called by muse, mutect2, varscan2
- SLITRK6 | c.1293C>T p.F431= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs775059929, COSV68389520, COSV68391055; called by mutect2, varscan2
- SMAP2 | c.657C>T p.S219= | Silent (SNP) | VAF 52/218 reads (24%) | catalogued as COSV65531850; called by muse, mutect2, varscan2
- SQOR | c.573C>T p.I191= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs1467319318, COSV52941113, COSV52942810; called by muse, mutect2, varscan2
- SRM | c.858C>G p.A286= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV65384848; called by muse, mutect2, varscan2
- SVIL | c.3081A>G p.G1027= (on ENST00000355867 / NM_021738.3; = p.G601= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs541630783, COSV63446016; called by muse, varscan2
- SYMPK | c.2670C>T p.F890= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV55614009; called by muse, mutect2, varscan2
- SYNJ1 | c.1710G>A p.K570= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV59152973; called by muse, mutect2, varscan2
- TBX5 | c.1233C>T p.T411= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs188839350, COSV59863552; called by muse, varscan2
- TCAF2 | c.2488C>T p.L830= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100633629; called by mutect2, varscan2
- TCERG1 | c.2139G>A p.R713= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57039926; called by muse, mutect2, varscan2
- TECRL | c.888C>T p.F296= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101169334, COSV67085358; called by muse, mutect2, varscan2
- TFDP1 | c.369C>T p.V123= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV64741661; called by muse, mutect2, varscan2
- TJP3 | c.1185G>A p.R395= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV53664441; called by muse, varscan2
- TLR7 | c.1377C>T p.V459= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV66124952; called by muse, mutect2, varscan2
- TMEM87A | c.1083C>T p.S361= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV67747654; called by muse, mutect2, varscan2
- TPRG1L | c.420A>G p.V140= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99573326; called by muse, mutect2, varscan2
- TRAV26-2 | c.31C>T p.L11= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- TRBV5-1 | c.192C>T p.F64= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- TREML1 | c.291G>A p.E97= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV58295272; called by muse, mutect2, varscan2
- TRIM33 | c.2098C>T p.L700= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs1356112891, COSV61824549; called by muse, mutect2, varscan2
- TRIM49 | c.291G>A p.R97= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- TTBK2 | c.2319C>T p.L773= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as COSV51157505; called by muse, mutect2, varscan2
- TTC21A | c.147C>T p.V49= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV57185891; called by muse, mutect2, varscan2
- UBR1 | c.2727G>A p.G909= | Silent (SNP) | VAF 40/171 reads (23%) | catalogued as COSV51933755; called by muse, mutect2, varscan2
- UNC79 | c.7494G>A p.Q2498= (on ENST00000393151 / NM_001346218.2; = p.Q2321= on NM_020818.5) | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV56400725; called by muse, mutect2, varscan2
- USP17L2 | c.1375C>T p.L459= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs761564697, COSV61556281; called by muse, mutect2, varscan2
- USP9X | c.5664T>C p.N1888= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV61072714; called by muse, varscan2
- UTP14A | c.1422G>A p.R474= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as COSV64087486; called by muse, mutect2, varscan2
- UTP14A | c.1914C>T p.G638= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100928963; called by muse, mutect2, varscan2
- UTP14A | c.1915C>T p.L639= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100928964; called by muse, mutect2, varscan2
- VAT1L | c.1098G>A p.R366= | Silent (SNP) | VAF 74/316 reads (23%) | catalogued as COSV56824705; called by muse, mutect2, varscan2
- VIT | c.1584C>T p.S528= (on ENST00000389975 / NM_001177969.1; = p.S543= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs1443611805, COSV64896545; called by muse, mutect2, varscan2
- WNT7A | c.984C>T p.F328= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53197279; called by muse, mutect2, varscan2
- ZCCHC14 | c.568T>C p.L190= (on ENST00000268616; = p.L327= on NM_015144.3) | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV51884563; called by muse, mutect2, varscan2
- ZCWPW2 | c.117G>A p.L39= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV67500122; called by mutect2, varscan2
- ZFAND6 | c.519C>T p.H173= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV55710755; called by muse, mutect2, varscan2
- ZKSCAN2 | c.375A>G p.K125= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs777966178, COSV60157985; called by muse, mutect2, varscan2
- ZNF208 | c.2304G>A p.K768= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV101236627, COSV68102134; called by muse, mutect2
- ZNF236 | c.4011C>T p.A1337= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs995495469, COSV53493503; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.840C>T p.Y280= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV53370110; called by muse, mutect2, varscan2
- ZNF653 | c.318C>T p.V106= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV53404054; called by muse, mutect2, varscan2
- ZNF778 | c.1962C>T p.F654= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1223463067, COSV60602305; called by mutect2, varscan2
- ZPLD1 | c.150G>A p.T50= (on ENST00000466937 / NM_001329788.1; = p.T66= on NM_175056.2) | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1396287804, COSV60352707; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846052 C>G | 5'Flank (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- AL645933.1 | chr6:31463846 G>A | 5'Flank (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- AMFR | c.*402G>A | 3'UTR (SNP) | VAF 12/51 reads (24%) | catalogued as rs1163027296, COSV99315944; called by muse, mutect2, varscan2
- CLASP1 | c.1912+2385C>T | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99755084; called by muse, mutect2, varscan2
- CPLANE1 | c.*3898T>A | 3'UTR (SNP) | VAF 13/48 reads (27%) | catalogued as COSV57068275; called by muse, mutect2, varscan2
- DSC1 | c.2488-122C>T | Intron (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99937166; called by muse, mutect2, varscan2
- DSC2 | c.2509-132G>A | Intron (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99199661; called by mutect2, varscan2
- FAM183BP | n.1236G>A | RNA (SNP) | VAF 48/172 reads (28%) | catalogued as rs777801963; called by mutect2, varscan2
- KIR3DX1 | n.150C>T | RNA (SNP) | VAF 17/66 reads (26%) | catalogued as COSV55599911; called by muse, mutect2, varscan2
- MFSD12 | chr19:3542867 ins T | 3'Flank (INS) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- MIR520B | n.11G>A | RNA (SNP) | VAF 17/59 reads (29%) | catalogued as rs1398354138; called by muse, mutect2, varscan2
- MSL3 | c.1171+22C>T | Intron (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100384832; called by muse, mutect2, varscan2
- NOS1 | c.2532-2242C>T | Intron (SNP) | VAF 28/109 reads (26%) | catalogued as COSV57617671; called by muse, mutect2, varscan2
- OFCC1 | n.393-2911G>A | Intron (SNP) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- OGG1 | c.948+20C>T | Intron (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99844775; called by muse, mutect2, varscan2
- OR52A4P | n.690C>T | RNA (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- PNO1 | chr2:68157654 T>A | 5'Flank (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- SLC22A18 | c.*2C>T | 3'UTR (SNP) | VAF 64/192 reads (33%) | catalogued as rs140109271, COSV100045252; called by muse, mutect2, varscan2
- SLC39A14 | c.457+1562C>T | Intron (SNP) | VAF 56/113 reads (50%) | catalogued as COSV99249795; called by muse, mutect2, varscan2
- SPATA16 | c.-2C>T | 5'UTR (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100651301; called by muse, mutect2, varscan2
- SYT1 | c.929-24807G>A | Intron (SNP) | VAF 5/23 reads (22%) | catalogued as rs866287531, COSV99695731; called by mutect2, varscan2
- TTN | c.10360+1407C>T | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100615414; called by mutect2, varscan2
- TUBB7P | n.220G>A | RNA (SNP) | VAF 9/71 reads (13%) | called by muse, varscan2
